Somatic mutation profile of tumor specimen TCGA-AX-A2H5-01A (aliquot TCGA-AX-A2H5-01A-11D-A17D-09) from TCGA case TCGA-AX-A2H5, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 67.8 years (24,757 days).
Specimen TCGA-AX-A2H5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ced2f67-f627-4000-a381-8a06dd99a5cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A2H5-11A (Solid Tissue Normal), aliquot TCGA-AX-A2H5-11A-11D-A17D-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d7f2b400-8f86-44d9-973b-ef613628d051

The open-access MAF lists 48 somatic variants for this specimen: 39 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 37, Silent 9, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMC1A | c.2131C>T p.R711W | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587784409, CM071102, COSV59127821; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.797G>T p.G266V | Missense Mutation (SNP) | VAF 46/48 reads (96%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs193920774, CM1414506, COSV52664019, COSV52666760, COSV53585299; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- BUB1B | c.86T>A p.V29E | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV55011021; called by muse, mutect2, varscan2
- CLSPN | c.3362A>C p.Y1121S | Missense Mutation (SNP) | VAF 64/103 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52048662; called by muse, mutect2, varscan2
- CNTNAP3 | c.3312C>A p.H1104Q | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.734); catalogued as COSV52665816; called by muse, mutect2, varscan2
- CPS1 | c.3538G>A p.A1180T | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs776047286, COSV51805628; called by muse, mutect2, varscan2
- DLX2 | c.579G>T p.Q193H | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52231809; called by muse, mutect2
- DMAP1 | c.502G>C p.D168H | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.715); catalogued as COSV60000265; called by muse, mutect2
- EPHB4 | c.1523G>C p.R508P | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100639533; called by mutect2, varscan2
- FAM135A | c.1195G>C p.D399H (on ENST00000370479 / NM_001351599.1; = p.D382H on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as COSV52049466; called by muse, mutect2, varscan2
- FBXO17 | c.703G>A p.V235I | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT tolerated (0.07); PolyPhen benign (0.085); catalogued as rs760219167, COSV53069266; called by muse, mutect2, varscan2
- HERC1 | c.8206G>A p.A2736T | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.977); catalogued as COSV71246916; called by muse, mutect2, varscan2
- HOXA1 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 38/64 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58029350; called by muse, mutect2, varscan2
- HUWE1 | c.8116G>A p.D2706N | Missense Mutation (SNP) | VAF 68/131 reads (52%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.077); catalogued as COSV53340143; called by muse, mutect2, varscan2
- IMPDH1 | c.995C>T p.T332I (on ENST00000470772 / NM_001142573.2; = p.T418I on NM_000883.4) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs988081022, COSV58315503; called by muse, mutect2, varscan2
- ITGA8 | c.997G>A p.D333N | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65226892; called by muse, mutect2, varscan2
- KIAA1522 | c.461G>T p.R154L (on ENST00000373480 / NM_001198972.2; = p.R213L on NM_020888.3) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.427); catalogued as COSV53863403; called by muse, mutect2, varscan2
- PCDHB12 | c.1709C>T p.A570V | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.059); catalogued as rs1554286996, COSV53394760; called by muse, mutect2, varscan2
- PDE8B | c.2425G>A p.E809K | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs898013072, COSV53735170; called by muse, mutect2, varscan2
- PDXK | c.331G>A p.V111M | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs895419033, COSV52361718; called by muse, mutect2, varscan2
- PHYHIP | c.874G>A p.V292I | Missense Mutation (SNP) | VAF 11/11 reads (100%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.555); catalogued as rs746137577, COSV58688288; called by muse, mutect2, varscan2
- POP4 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 13/459 reads (3%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV55676193; called by muse, mutect2
- PRELP | c.71G>C p.R24T | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV58115533; called by muse, mutect2
- PUM1 | c.3312G>A p.M1104I | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV57083535; called by muse, mutect2, varscan2
- RELN | c.3441C>G p.D1147E | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.97); catalogued as COSV58993945; called by muse, mutect2, varscan2
- RPAP1 | c.379G>A p.V127I | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.73); PolyPhen benign (0.041); catalogued as COSV58538018; called by muse, mutect2, varscan2
- RSU1 | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs200600927, COSV61710188, COSV61711916; called by muse, mutect2, varscan2
- SLC12A2 | c.2979A>T p.E993D | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs764157245, COSV52469866; called by muse, mutect2, varscan2
- SLC5A9 | c.1417G>A p.A473T | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.377); catalogued as rs771834200, COSV52581791; called by muse, mutect2, varscan2
- SV2C | c.1250T>G p.I417S | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as COSV59217502; called by muse, mutect2, varscan2
- TTLL5 | c.1867A>T p.T623S | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54030678; called by muse, mutect2, varscan2
- UBB | c.93G>T p.Q31H | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as COSV56218555; called by muse, mutect2
- UFL1 | c.442C>T p.L148F | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as COSV65149679; called by muse, mutect2, varscan2
- VPS13D | c.7694C>G p.P2565R | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.71); catalogued as COSV50629801; called by muse, mutect2, varscan2
- WASHC4 | c.1048A>T p.I350F | Missense Mutation (SNP) | VAF 53/82 reads (65%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV59889042; called by muse, mutect2, varscan2
- WDR41 | c.1270G>A p.A424T | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.561); catalogued as rs146353207, COSV53735177; called by muse, varscan2
- ZNF266 | c.538G>A p.G180R | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0.033); catalogued as COSV63221752; called by muse, mutect2
- H2AC17 | c.343_344dup p.L116Yfs*19 | Frame Shift Ins (INS) | VAF 44/118 reads (37%) | called by mutect2, varscan2
- RFC1 | c.3041_3043del p.G1014del (on ENST00000381897 / NM_001363496.2; = p.G1013del on NM_002913.5 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 32/74 reads (43%) | called by mutect2, varscan2
- ATP11C | c.1746G>A p.E582= | Silent (SNP) | VAF 8/100 reads (8%) | catalogued as COSV59561303; called by muse, mutect2
- MAS1L | c.1107C>A p.P369= | Silent (SNP) | VAF 29/74 reads (39%) | catalogued as COSV101009697, COSV65808739; called by muse, mutect2, varscan2
- MTHFR | c.1494G>C p.V498= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV57171883; called by muse, mutect2, varscan2
- OPRK1 | c.963C>T p.T321= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as COSV55569403, COSV99653862; called by muse, mutect2
- SETD1A | c.5086C>T p.L1696= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs1219140788, COSV52680107, COSV99352628; called by muse, mutect2, varscan2
- TJP3 | c.1866G>A p.V622= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV53661611; called by muse, mutect2, varscan2
- TRAPPC10 | c.1632C>T p.L544= | Silent (SNP) | VAF 24/98 reads (24%) | catalogued as COSV52376146, COSV52376424; called by muse, mutect2, varscan2
- VWA5A | c.1209A>G p.V403= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV63707447; called by muse, mutect2, varscan2
- ZNF212 | c.453C>T p.T151= | Silent (SNP) | VAF 28/50 reads (56%) | catalogued as rs538640431, COSV60024846; called by muse, mutect2, varscan2
